Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4ND, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4ND-01A (Primary Tumor).

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 A11 A12 A13

Left lobe liver (915.0 grams, 13.5 x 13.0 x 8.0 cm).

DIAGNOSIS:

Liver, left lobe, resection: Grade 3 (of 4) hepatocellular carcinoma forms a 13.0 x 13.0 x 7.5 cm intrahepatic mass with focal necrosis. No vascular invasion identified. Margins of resection negative for tumor (closest margin 1.2 cm). Uninvolved liver is noncirrhotic

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

JW 12/24/12

JW 9/20/12

Source: NCI Genomic Data Commons file 1e4e0dd7-14a1-455a-950c-15c18624e7b5 (TCGA-DD-A4ND.64D878AE-DEEA-4C56-854C-3774038E2914.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).